CCDI case PBBPJU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ed643a50-e472-470a-9a8d-7fbca596b828

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, anaplastic: ICD-O-3 morphology code: 9392/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.0 years (5,492 days).

Biospecimens (3 samples)
- Sample 0DDZ62: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DDZ6M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DEK18: Tissue type: Tumor; Specimen type: Solid Tissue.
